CCDI case PBCHFP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/41ab3d6b-1fa4-4ac5-bede-d0d0b2838251

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Leydig cell tumor, benign: ICD-O-3 morphology code: 8650/0; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 8.4 years (3,080 days).

Biospecimens (3 samples)
- Sample 0DRXE8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRXEK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRXEV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
